Somatic mutation profile of tumor specimen TCGA-BP-4968-01A (aliquot TCGA-BP-4968-01A-01D-1462-08) from TCGA case TCGA-BP-4968, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 40.1 years (14,651 days).
Specimen TCGA-BP-4968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54118f0f-a3b0-4fc1-a040-a3182105c788.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4968-11A (Solid Tissue Normal), aliquot TCGA-BP-4968-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4533f483-45ab-4d18-94a0-490cda339a7d

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 3, Splice Region 3, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | hotspot (GDC flag); catalogued as rs869025617, CM003058, CM971566, COSV56542559, COSV56566398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5451G>A p.L1817= (on ENST00000614293; = p.L1787= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/69 reads (26%) | catalogued as COSV55806684; called by muse, mutect2, varscan2
- ABCA5 | c.703T>A p.F235I | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV67019088; called by muse, mutect2, varscan2
- ACLY | c.1005C>A p.G335= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as COSV61252975; called by muse, mutect2, varscan2
- ADAMTS14 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs764935842, COSV64606405, COSV64606516; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1506A>T p.E502D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV52355242; called by muse, mutect2, varscan2
- CDH12 | c.2082A>T p.K694N | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.741); catalogued as COSV66447567; called by muse, varscan2
- CDH24 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.549); catalogued as rs755865066, COSV57463521; called by muse, mutect2
- CFAP54 | c.5307G>T p.Q1769H | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV61575196; called by muse, mutect2, varscan2
- DNAH9 | c.12777T>A p.C4259* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV52376682; called by muse, mutect2, varscan2
- ELF2 | c.749G>A p.W250* (on ENST00000379550 / NM_001331036.2; = p.W190* on NM_006874.4) | Nonsense Mutation (SNP) | VAF 61/220 reads (28%) | catalogued as COSV55495688; called by muse, mutect2, varscan2
- ESPL1 | c.2414G>T p.R805I | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs750838036, COSV57763290; called by muse, mutect2, varscan2
- FAM168A | c.296C>T p.A99V (on ENST00000064778 / NM_001286050.2; = p.A90V on NM_015159.3) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); catalogued as rs779693765, COSV50359338; called by muse, mutect2, varscan2
- GFRAL | c.513A>G p.I171M | Missense Mutation (SNP) | VAF 10/343 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV61235368; called by muse, mutect2
- HMG20A | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60314223; called by muse, mutect2, varscan2
- KCNH4 | c.585T>C p.N195= | Splice Region (SNP) | VAF 49/206 reads (24%) | catalogued as rs1222056771, COSV52921030; called by muse, varscan2
- MYH2 | c.3118C>T p.L1040F | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55448235; called by muse, mutect2, varscan2
- ORC5 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52402725; called by muse, mutect2
- PARP15 | c.1280C>T p.A427V (on ENST00000464300 / NM_001113523.3; = p.A193V on NM_152615.2) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59975042; called by muse, mutect2
- PAX9 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV64061190; called by muse, mutect2, varscan2
- PDE3B | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56390619; called by muse, mutect2, varscan2
- PNP | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64092297; called by muse, mutect2, varscan2
- PRDM5 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374583073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX7 | c.112A>T p.S38C (on ENST00000559447 / NM_001368074.1; = p.S135C on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57968780; called by muse, mutect2, varscan2
- SECISBP2 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 129/402 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59400853; called by muse, mutect2, varscan2
- SEZ6L | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as rs746856153, COSV50686996; called by muse, mutect2, varscan2
- SIRT4 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52542063; called by muse, mutect2, varscan2
- TSKS | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV55879263; called by muse, mutect2, varscan2
- TTC13 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as rs777528572, COSV64170004; called by muse, mutect2, varscan2
- XAB2 | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV64322369, COSV64322776; called by muse, mutect2, varscan2
- ZFP36L2 | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV56700167; called by muse, mutect2, varscan2
- ZNF800 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56179956; called by muse, mutect2, varscan2
- HEATR9 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MMP9 | c.1419del p.T474Lfs*36 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- NRCAM | c.1569_1570dup p.T524Ifs*9 (on ENST00000379028 / NM_001371124.1; = p.T518Ifs*9 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 64/272 reads (24%) | called by mutect2, pindel, varscan2
- RNF213 | c.12345dup p.S4116Ifs*7 | Frame Shift Ins (INS) | VAF 58/232 reads (25%) | called by mutect2, pindel, varscan2
- ADAM29 | c.219G>A p.L73= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs759542611, COSV63666977, COSV63668141; called by muse, mutect2, varscan2
- APOBEC1 | c.27C>T p.T9= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs760987232, COSV57550219; called by muse, mutect2, varscan2
- EPHA8 | c.1542C>G p.A514= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV51299125; called by muse, varscan2
- H2BC4 | c.6T>C p.P2= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV58417601; called by muse, mutect2
- MARCHF8 | c.222A>T p.P74= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV60574866; called by muse, mutect2, varscan2
- PLEKHG5 | c.1182G>C p.V394= (on ENST00000400915 / NM_001042663.3; = p.V357= on NM_020631.6) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV61705988; called by muse, mutect2, varscan2
- PROX1 | c.1503C>T p.S501= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs1327610029, COSV54783674; called by muse, mutect2, varscan2
- SLC22A6 | c.1482T>C p.P494= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as COSV64561089; called by muse, mutect2, varscan2
- SYNJ1 | c.177C>T p.L59= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV59156553; called by muse, mutect2, varscan2
- CPLANE1 | c.*3235T>G | 3'UTR (SNP) | VAF 68/211 reads (32%) | catalogued as COSV57059600; called by muse, mutect2, varscan2
